Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A85H, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A85H-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor occupies bladder wall. It is invasive and protruded, ill - margins with 2x1.5x1.2cm in size, soft and gray surface.

Microscopic Description: Tumor cells are hyperplastic to arrange to form sheets or nest or groups or cords one by one. Tumor cells have moderate and eosinophilic. Nuclei are very enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are common. Tumor invades in musculari propria and vessel.

Diagnosis Details: Infiltrating urothelial carcinoma, high-grade, infiltrating in one half of muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 2 x 1.5 x 1.2 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

Lymph nodes: 0/2 positive for metastasis (Inguinal lymph node 0/2)

Lymphatic invasion: Not specified

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Focal extracapsular extension (bladder wall, vessel)

Comments: None

CGLE *ICD O-3*
Carcinoma, urothelial NOS *8/20/13*
path
Carcinoma, transitional cell *8/20/13*
CGLE
Site: Bladder NOS *8/20/13*
path
Bladder wall *8/20/13*
7/25/14

Source: NCI Genomic Data Commons file b30342d9-e484-4ba6-83d7-bb05d305f7bf (TCGA-E7-A85H.4AAC565F-AE74-46E9-87D1-055DD38EFEBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).